Somatic mutation profile of tumor specimen 0DHE04 from CCDI case PBBUGH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.0 years (4,370 days).
Specimen 0DHE04: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43ed7873-2111-4e04-a8cf-a20c8b1ac4f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHDZE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c89f66b9-c1a0-4751-ae84-adf62268c44c

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Intron 3, Frame Shift Ins 2, Frame Shift Del 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 254/575 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- ENPP3 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 287/294 reads (98%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs780707010; called by muse, mutect2, varscan2
- FANCD2 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 90/672 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs754258198, COSV55034828; called by muse, mutect2
- FARS2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 40/682 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223957, COSV51165671; ClinVar: uncertain significance; called by muse, mutect2
- HHIPL1 | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 127/305 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1390452090; called by muse, mutect2, varscan2
- HOXB9 | c.440T>A p.V147E | Missense Mutation (SNP) | VAF 50/628 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV60817022; called by muse, mutect2
- JHY | c.776dup p.N259Kfs*21 | Frame Shift Ins (INS) | VAF 264/508 reads (52%) | catalogued as rs756113544; called by mutect2, varscan2
- MUC12 | c.12310G>A p.V4104I (on ENST00000379442; = p.V3961I on NM_001164462.1) | Missense Mutation (SNP) | VAF 136/3152 reads (4%) | SIFT tolerated (0.27); catalogued as rs760054836, COSV65189490; called by muse, mutect2
- PCDHB11 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100696907; called by muse, mutect2, varscan2
- TEK | c.3296G>A p.R1099Q | Missense Mutation (SNP) | VAF 116/304 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs759970580, COSV66231648; called by muse, mutect2, varscan2
- ZBTB37 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 200/441 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1397528699, COSV100875295; called by muse, mutect2, varscan2
- AGTR2 | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 16/499 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPEB4 | c.872del p.P291Rfs*31 | Frame Shift Del (DEL) | VAF 137/385 reads (36%) | called by mutect2, pindel, varscan2
- SOX4 | c.150dup p.W51Lfs*72 | Frame Shift Ins (INS) | VAF 50/348 reads (14%) | called by mutect2, pindel, varscan2
- SOX4 | c.313_318dup p.K105_I106dup | In Frame Ins (INS) | VAF 268/404 reads (66%) | called by mutect2, varscan2
- TEP1 | c.2368G>C p.D790H | Missense Mutation (SNP) | VAF 27/552 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2
- ZNF532 | c.2675A>G p.Q892R | Missense Mutation (SNP) | VAF 34/686 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- CAMK2B | c.474C>T p.F158= | Silent (SNP) | VAF 229/541 reads (42%) | catalogued as rs1367462372, COSV51659321; called by muse, mutect2, varscan2
- DCDC2C | c.702A>G p.E234= | Silent (SNP) | VAF 63/804 reads (8%) | called by muse, mutect2
- EYS | c.6255G>T p.G2085= | Silent (SNP) | VAF 449/485 reads (93%) | called by muse, mutect2, varscan2
- GP1BB | c.219G>A p.G73= | Silent (SNP) | VAF 191/425 reads (45%) | catalogued as rs897029998; called by muse, mutect2, varscan2
- GRK4 | c.894C>T p.C298= (on ENST00000398052 / NM_182982.3; = p.C266= on NM_005307.3) | Silent (SNP) | VAF 205/563 reads (36%) | catalogued as rs770625534; called by muse, mutect2, varscan2
- PGGHG | c.2181C>T p.T727= | Silent (SNP) | VAF 37/677 reads (5%) | catalogued as rs765928223, COSV66888682; called by muse, mutect2
- ANKRD30B | c.-87A>C | 5'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2
- NCAPH | c.1357+18G>A | Intron (SNP) | VAF 120/332 reads (36%) | called by muse, mutect2, varscan2
- PLCB2 | c.582+333C>T | Intron (SNP) | VAF 113/268 reads (42%) | catalogued as rs1057434826; called by muse, mutect2, varscan2
- TTN | c.62714-28A>G | Intron (SNP) | VAF 104/216 reads (48%) | called by muse, mutect2
